Somatic mutation profile of tumor specimen 0DHY4I from CCDI case PBBUWT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.4 years (4,534 days).
Specimen 0DHY4I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1450128-c60f-4333-8ef3-1d2f4498dd71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/735e1bb5-1e17-4ddc-8b35-64911bc1f9fa

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'UTR 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47A | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 176/428 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as COSV60500448; called by muse, mutect2, varscan2
- FUBP3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 36/648 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs768069231, COSV100156292; called by muse, mutect2
- HGFAC | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755274674; called by muse, mutect2, varscan2
- KIAA0319L | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 283/669 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs764655401, COSV57844637; called by muse, mutect2, varscan2
- KIR2DL3 | c.71-2A>T p.X24_splice | Splice Site (SNP) | VAF 104/458 reads (23%) | catalogued as rs1381454233; called by muse, mutect2
- NOS3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 48/588 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as rs750247122, COSV52495450; called by muse, mutect2
- RBFOX1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 242/557 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs1308872865; called by muse, mutect2, varscan2
- CENPVL3 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); called by muse, mutect2
- KCND1 | c.474C>A p.D158E | Missense Mutation (SNP) | VAF 17/498 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- PNLIP | c.126del p.H42Qfs*54 | Frame Shift Del (DEL) | VAF 287/603 reads (48%) | called by mutect2, varscan2
- SCX | c.462C>T p.R154= | Silent (SNP) | VAF 217/414 reads (52%) | called by muse, mutect2, varscan2
- SPOCK3 | c.213C>T p.R71= | Silent (SNP) | VAF 175/464 reads (38%) | catalogued as rs760901431; called by muse, mutect2, varscan2
- HEY1 | c.-79A>G | 5'UTR (SNP) | VAF 98/194 reads (51%) | called by muse, mutect2, varscan2
- SMARCD1 | chr12:50085309 del G | 5'Flank (DEL) | VAF 82/182 reads (45%) | called by mutect2, varscan2
